Somatic mutation profile of tumor specimen HCM-BROD-0130-C25-06A (aliquot HCM-BROD-0130-C25-06A-01D-A78W-36) from HCMI case HCM-BROD-0130-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.6 years (21,030 days).
Specimen HCM-BROD-0130-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6560715-a63f-4000-873c-a04820260d5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0130-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0130-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f6fb119-d5d7-4a60-9ec4-ce1415cad166

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, In Frame Del 1, Nonsense Mutation 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FAM47C | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs782254765, COSV100792660; called by muse, mutect2, varscan2
- FOXJ1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs1318544381; called by muse, mutect2, varscan2
- GPIHBP1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746247359, COSV58209384; called by muse, mutect2
- ITGA9 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374110267; called by muse, mutect2, varscan2
- KMT2C | c.4174C>T p.Q1392* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as COSV51426883; called by muse, mutect2
- NLRP3 | c.1884G>C p.L628F | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV60230250; called by muse, mutect2, varscan2
- OTUD7A | c.943G>A p.V315I (on ENST00000307050 / NM_001382637.1; = p.V308I on NM_130901.3) | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61038042; called by muse, mutect2, varscan2
- PCDHB2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 118/972 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs782682660, COSV99164149, COSV99166535; called by muse, mutect2, varscan2
- SAMD9 | c.2063A>G p.K688R | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1188656521; called by muse, mutect2, varscan2
- TMEM132A | c.2992C>T p.R998C (on ENST00000453848 / NM_178031.3; = p.R999C on NM_017870.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs368115669; called by muse, mutect2, varscan2
- ZCCHC12 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746217095, COSV59573098; called by muse, mutect2, varscan2
- AGBL2 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 101/547 reads (18%) | called by mutect2, pindel, varscan2
- EML6 | c.2657A>G p.D886G | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- HERC2 | c.8305C>G p.R2769G | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SUPT6H | c.3643C>A p.H1215N | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D3F | c.73-1G>A p.X25_splice | Splice Site (SNP) | VAF 59/472 reads (13%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.3655T>C p.S1219P | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1RL | c.360C>T p.G120= | Silent (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- CTXN2 | c.243G>A p.A81= | Silent (SNP) | VAF 81/209 reads (39%) | catalogued as rs182590178; called by mutect2, varscan2
- PKD1L1 | c.3945T>C p.S1315= | Silent (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- PTGFR | c.300C>A p.R100= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV66115799; called by muse, mutect2, varscan2
- ZNF566 | c.408G>A p.G136= | Silent (SNP) | VAF 26/346 reads (8%) | called by muse, mutect2
- BDKRB2 | chr14:96204838 C>T | 5'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
